Gene-level copy-number profile of tumor specimen TCGA-66-2768-01A from TCGA case TCGA-66-2768, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 57.4 years (20,970 days).
Specimen TCGA-66-2768-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2e203c70-0f6a-4400-a62a-7846b87f1d80.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2768-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/afed7713-22c7-4996-ace7-df2cedc9e40e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,415; copy number 2: 43,890; copy number 3: 1,337; copy number 4: 1,354; copy number 5: 645; copy number 6: 57; copy number 7: 5; copy number 8: 5; copy number 12: 31; copy number 15: 37; copy number 21: 25; copy number 24: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2768-01A-01D-0844-01): tumor purity 0.57, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 809 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:40,909,497–40,984,643, 1 gene, copy number 5 (within-gene range 3–5): C7.
- chr5:40,967,505–40,967,763, 1 gene, copy number 5: AC114967.1.
- chr5:41,306,952–43,886,628, 57 genes, copy number 6: PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1.
- chr11:69,294,151–77,026,797, 266 genes, copy number 5–24 (broad region; genes not listed).
- chr11:81,821,272–82,718,299, 4 genes, copy number 5 (within-gene range 1–5): MIR4300HG, AP002802.2, MIR4300, AP002802.1.
- chr16:55,007,982–68,448,508, 330 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr18:29,048,620–32,773,023, 61 genes, copy number 7–21 (within-gene range 1–21) (broad region; genes not listed).
- chr19:8,413,270–10,231,286, 89 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,005. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
